TCGA case TCGA-D8-A1JI — Breast Invasive Carcinoma (TCGA-BRCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Ductal and Lobular Neoplasms; Primary site: Breast; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/baf2afc8-f16c-488f-947c-efc9083c6bef

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C50.9; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 55.0 years (20,072 days); Year of diagnosis: 2010; Method of diagnosis: Fine Needle Aspiration; AJCC staging edition: 7th; AJCC pathologic T: T1c; AJCC pathologic N: N1a; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Breast, Right Upper Outer.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 2; Lymph nodes tested: 22; Micrometastasis present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Days to treatment start: 41 days; Days to treatment end: 162 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Doxorubicin; Treatment intent type: Adjuvant; Days to treatment start: 41 days; Days to treatment end: 162 days; Number of cycles: 6; Prescribed dose: 2.5; Prescribed dose units: mg/m2/day; Route of administration: Intravenous.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Letrozole; Days to treatment start: 41 days; Days to treatment end: 162 days.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 204 days; Days to treatment end: 231 days; Number of fractions: 20; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: First-Line Therapy; Initial disease status: Initial Diagnosis; Margin status: Uninvolved; Treatment anatomic sites: Breast.

Follow-up (2 entries)
- Days to follow up: 21 days; Disease response: Tumor Free.
- Days to follow up: 577 days (1.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- ERBB2 (IHC): Negative.
- ESR1 (IHC): Positive.
- PGR (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D8-A1JI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 190 mg.
  Slide TCGA-D8-A1JI-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
- Sample TCGA-D8-A1JI-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D8-A1JI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: Yes; Er positivity method: manual counting; Pr positivity define method: manual counting; Axillary staging method: Axillary lymph node dissection alone; Surgical procedure first: Modified Radical Mastectomy; Histologic diagnosis: Infiltrating Ductal Carcinoma; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); Micromet detection by IHC: No; Method initial path diagnosis: Fine needle aspiration biopsy; Pr positivity scale other: >75%; Er positivity scale other: >75%; Her2 positivity method text: DAKOHercepTest TM; Prospective collection: Yes; Retrospective collection: No.
- Anatomic neoplasm subdivisions: Anatomic organ subdivision: Right Upper Outer Quadrant.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: doxorubicine.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: letrozolum.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 577 days; disease-specific survival: no event (censored), 577 days; disease-free interval: no event (censored), 577 days; progression-free interval: no event (censored), 577 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D8-A1JI-01A-11D-A13J-01): tumor purity 0.89, ploidy 1.76, whole-genome doublings 0.
